Somatic mutation profile of tumor specimen TCGA-AC-A3QQ-01A (aliquot TCGA-AC-A3QQ-01A-11D-A228-09) from TCGA case TCGA-AC-A3QQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 54.0 years (19,723 days).
Specimen TCGA-AC-A3QQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50ad52a9-4db9-4473-a8a0-3a7e1d8a2f16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A3QQ-10A (Blood Derived Normal), aliquot TCGA-AC-A3QQ-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b503b056-88e9-4a2d-a9f4-4017611d8799

The open-access MAF lists 28 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 20, Silent 4, Nonsense Mutation 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- AAK1 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416755652, COSV101275992; called by muse, mutect2, varscan2
- C2 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100191255, COSV54961650; called by muse, mutect2, varscan2
- CBFB | c.188A>T p.N63I | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52000610, COSV99325828; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as COSV99267433; called by muse, mutect2, varscan2
- COL6A3 | c.8020T>G p.S2674A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.339); catalogued as COSV99799600; called by muse, mutect2, varscan2
- CWH43 | c.1338T>A p.S446R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99893653; called by mutect2, varscan2
- DNAAF3 | c.68T>A p.L23Q (on ENST00000524407 / NM_001256715.2; = p.L70Q on NM_178837.4) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV100845920; called by muse, mutect2, varscan2
- DUOX2 | c.1731C>A p.D577E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101199813, COSV66533406; called by muse, mutect2, varscan2
- FLNA | c.4341T>A p.D1447E | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV100774883; called by muse, mutect2, varscan2
- FTHL17 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.117); catalogued as COSV63267733; called by muse, mutect2, varscan2
- HAVCR2 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367701067; called by muse, mutect2, varscan2
- IRX6 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs200849204, COSV99306618; called by muse, mutect2, varscan2
- MCF2L | c.2307G>T p.Q769H (on ENST00000375608; = p.Q737H on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99995776, COSV99995948; called by muse, mutect2, varscan2
- PKDREJ | c.3517C>T p.R1173W | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs546765847, COSV53550947, COSV53552415; called by muse, mutect2
- RNF144A | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as rs545761424, COSV57979881; called by muse, mutect2, varscan2
- TOR1AIP1 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.022); catalogued as COSV99621490; called by muse, mutect2
- TRUB1 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100076138; called by muse, mutect2, varscan2
- TTN | c.12592A>T p.K4198* (on ENST00000591111; = p.K4152* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100619980; called by muse, mutect2, varscan2
- TYRO3 | c.1805T>A p.I602N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99777811; called by muse, mutect2, varscan2
- VWA1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1014142835, COSV58600751; called by muse, mutect2, varscan2
- ZNF536 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100835448; called by muse, mutect2, varscan2
- CCNO | c.990del p.L331* | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- HTT | c.6926_6928del p.Y2309del | In Frame Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- ACTN3 | c.1314G>A p.S438= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs371957271; called by muse, mutect2, varscan2
- FBP1 | c.460C>T p.L154= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs539871294, COSV100941281; called by muse, mutect2, varscan2
- IHH | c.405G>A p.E135= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV55394025, COSV99838723; called by muse, mutect2, varscan2
- RPUSD4 | c.1035T>G p.L345= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as COSV100028799; called by muse, mutect2, varscan2
